Somatic mutation profile of tumor specimen TCGA-P5-A781-01A (aliquot TCGA-P5-A781-01A-11D-A32B-08) from TCGA case TCGA-P5-A781, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.9 years (12,757 days).
Specimen TCGA-P5-A781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d60f8e0d-1860-4456-aa5a-9edc133fb41a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A781-10A (Blood Derived Normal), aliquot TCGA-P5-A781-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/104593e4-f820-47e8-aeed-8ec29ff61e6b

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AMER1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs147754688, COSV100366837; called by muse, mutect2, varscan2
- CALML6 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100205639; called by muse, mutect2
- DACH2 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as rs780882514, COSV100913696, COSV64185566; called by muse, mutect2, varscan2
- HUWE1 | c.9810C>A p.D3270E | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782099367, COSV99473601; called by muse, mutect2, varscan2
- RIN2 | c.1117C>T p.R373W (on ENST00000255006 / NM_001242581.1; = p.R324W on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs1376170735, COSV54784052, COSV99657639; called by muse, mutect2, varscan2
- SLK | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs140715399; called by muse, mutect2
- TRIM27 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs545778548, COSV101019300; called by muse, mutect2, varscan2
- MLLT6 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- BBOX1 | c.96A>G p.V32= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs780510064, COSV99589895; called by mutect2, varscan2
- DENND3 | c.2184C>T p.S728= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs777757517, COSV99371443; called by muse, mutect2, varscan2
- SLC30A8 | c.873T>A p.I291= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV101438713; called by muse, mutect2
